Somatic mutation profile of tumor specimen C3N-06044-01 (aliquot CPT0438760008) from CPTAC case C3N-06044, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 65.6 years (23,945 days).
Specimen C3N-06044-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 30f9d682-25e7-4881-8f76-934ad0dc9267.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-06044-31 (Blood Derived Normal), aliquot CPT0444820004; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d4d9a4c8-c016-42ef-af6e-cef649458e05

The open-access MAF lists 200 somatic variants for this specimen: 140 protein-altering or splice-affecting, 54 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 131, Silent 54, Nonsense Mutation 5, Splice Region 3, Intron 2, 3'Flank 2, 3'UTR 1, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.5164C>T p.R1722* | Nonsense Mutation (SNP) | VAF 53/461 reads (11%) | hotspot (GDC flag); catalogued as rs1485978447, COSV61371609; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 122/331 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CDK4 | c.64A>C p.K22Q | Missense Mutation (SNP) | VAF 115/458 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1555201381, COSV56983663; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.825T>G p.C275W | Missense Mutation (SNP) | VAF 94/455 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1555525279, CM152980, COSV52759232, COSV52912941, COSV53086963; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AC073111.3 | c.406C>T p.P136S | Missense Mutation (SNP) | VAF 64/992 reads (6%) | SIFT tolerated (0.56); PolyPhen benign (0.023); catalogued as rs570465093; called by muse, mutect2
- ARHGEF35 | c.1391C>T p.S464F | Missense Mutation (SNP) | VAF 101/898 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV65312402; called by muse, mutect2, varscan2
- ASAH2 | c.1640G>A p.R547Q | Missense Mutation (SNP) | VAF 39/258 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1159380115; called by muse, mutect2, varscan2
- ATP1A1 | c.791G>A p.R264H | Missense Mutation (SNP) | VAF 38/610 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs765069962; called by muse, mutect2
- B3GNT3 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 58/538 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764743027, COSV59438389; called by muse, mutect2, varscan2
- BAIAP2L2 | c.1233G>A p.M411I | Missense Mutation (SNP) | VAF 104/542 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV100260178; called by mutect2, varscan2
- CFAP47 | c.4451G>A p.G1484E | Missense Mutation (SNP) | VAF 39/171 reads (23%) | SIFT tolerated (0.97); PolyPhen benign (0.018); catalogued as COSV57975766; called by muse, mutect2, varscan2
- COL4A4 | c.4835G>A p.G1612E | Missense Mutation (SNP) | VAF 52/565 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61630398; called by muse, mutect2
- COL4A4 | c.4834G>A p.G1612R | Missense Mutation (SNP) | VAF 49/566 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100307260; called by muse, mutect2
- COLEC12 | c.38C>T p.S13F | Missense Mutation (SNP) | VAF 47/416 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV68370666; called by muse, mutect2, varscan2
- CPM | c.460C>T p.R154* | Nonsense Mutation (SNP) | VAF 28/334 reads (8%) | catalogued as rs770112320; called by muse, mutect2
- CPNE4 | c.389C>T p.S130F | Missense Mutation (SNP) | VAF 23/349 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as COSV70196930, COSV70197493; called by muse, mutect2
- CTAGE1 | c.1751C>T p.P584L | Missense Mutation (SNP) | VAF 35/413 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV66945112; called by muse, mutect2
- DUSP6 | c.400G>A p.G134S | Missense Mutation (SNP) | VAF 27/406 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs764598740, COSV54379638; called by muse, mutect2
- EFHD1 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 71/897 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1274561519; called by muse, mutect2
- EHD2 | c.1313C>T p.S438L | Missense Mutation (SNP) | VAF 54/587 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs748070989, COSV99622026; called by muse, mutect2, varscan2
- ELP1 | c.3424C>T p.R1142* | Nonsense Mutation (SNP) | VAF 44/348 reads (13%) | catalogued as rs768015419, COSV65898615; called by muse, varscan2
- EYA1 | c.305C>T p.S102F | Missense Mutation (SNP) | VAF 42/528 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.141); catalogued as COSV100379816; called by muse, mutect2
- F11R | c.409G>A p.V137I | Missense Mutation (SNP) | VAF 69/441 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.018); catalogued as rs1162089487; called by muse, mutect2, varscan2
- FAM135B | c.2948G>A p.G983D | Missense Mutation (SNP) | VAF 54/638 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1311106365, COSV99428295; called by muse, mutect2
- FCRL4 | c.232C>T p.R78W | Missense Mutation (SNP) | VAF 100/670 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.849); catalogued as rs768413114; called by muse, mutect2, varscan2
- FLT1 | c.65G>A p.G22E | Missense Mutation (SNP) | VAF 10/334 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV56728770, COSV56731077; called by muse, mutect2
- FREM1 | c.3049G>A p.V1017I | Missense Mutation (SNP) | VAF 54/602 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.02); catalogued as rs1430894870; called by muse, mutect2
- FRMD4B | c.1867C>T p.H623Y | Missense Mutation (SNP) | VAF 46/391 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as rs866199441, COSV68332191; called by muse, mutect2, varscan2
- GOLGA8F | c.490G>A p.E164K (on ENST00000526619; = p.E370K on NM_001350920.2) | Missense Mutation (SNP) | VAF 32/430 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1217625410; called by muse, mutect2
- GPAT3 | c.692C>T p.S231F | Missense Mutation (SNP) | VAF 67/273 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); catalogued as rs553068392, COSV52358232; called by muse, mutect2, varscan2
- GPATCH11 | c.591A>T p.Q197H (on ENST00000409774; = p.Q175H on NM_174931.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/237 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1015832919; called by muse, mutect2
- GRID2 | c.2153C>T p.S718L | Missense Mutation (SNP) | VAF 89/364 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.049); catalogued as rs757924739, COSV56192980; called by muse, mutect2, varscan2
- HMCN1 | c.14365C>T p.P4789S | Missense Mutation (SNP) | VAF 52/616 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54918272, COSV54933643; called by muse, mutect2
- HMCN1 | c.14366C>T p.P4789L | Missense Mutation (SNP) | VAF 52/620 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54927013; called by muse, mutect2
- HP | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 38/371 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs761271318; called by muse, mutect2, varscan2
- HSP90B1 | c.744C>T p.T248= | Splice Region (SNP) | VAF 18/147 reads (12%) | catalogued as rs149843361; called by muse, mutect2, varscan2
- IGKV1-8 | c.49G>A p.G17S | Missense Mutation (SNP) | VAF 104/611 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.255); catalogued as rs1202640550; called by muse, mutect2, varscan2
- IGSF3 | c.233C>T p.S78F | Missense Mutation (SNP) | VAF 80/704 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV59587335; called by muse, mutect2, varscan2
- IKZF1 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 76/606 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as COSV58791093; called by muse, mutect2, varscan2
- IRAK3 | c.418C>T p.P140S | Missense Mutation (SNP) | VAF 34/166 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.044); catalogued as COSV99706070; called by muse, varscan2
- ITGA4 | c.643G>T p.A215S | Missense Mutation (SNP) | VAF 46/186 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52004439; called by muse, mutect2, varscan2
- KCNIP3 | c.367C>T p.P123S | Missense Mutation (SNP) | VAF 33/463 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV54665960; called by muse, mutect2
- KPRP | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 111/689 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs759181630, COSV100908771; called by muse, mutect2, varscan2
- MED8 | c.523C>T p.P175S | Missense Mutation (SNP) | VAF 41/404 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV99318548; called by muse, mutect2, varscan2
- MYO15A | c.1976C>T p.A659V | Missense Mutation (SNP) | VAF 91/396 reads (23%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.007); catalogued as rs1207739977; called by muse, mutect2, varscan2
- NDN | c.28G>A p.D10N | Missense Mutation (SNP) | VAF 43/365 reads (12%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.001); catalogued as COSV100086167; called by muse, mutect2, varscan2
- NMNAT3 | c.250G>A p.E84K (on ENST00000296202 / NM_001320512.1; = p.E47K on NM_178177.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/586 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1266343929; called by muse, mutect2
- PAX7 | c.1276C>T p.R426W | Missense Mutation (SNP) | VAF 78/748 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs769536224, COSV100946625; called by muse, mutect2, varscan2
- PCLO | c.8633G>A p.G2878D | Missense Mutation (SNP) | VAF 31/752 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.116); catalogued as COSV61672565; called by muse, mutect2
- PDE10A | c.1567C>T p.P523S | Missense Mutation (SNP) | VAF 49/473 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV63102942; called by muse, mutect2, varscan2
- PDZRN4 | c.2257G>C p.D753H (on ENST00000402685 / NM_001164595.2; = p.D495H on NM_013377.4) | Missense Mutation (SNP) | VAF 26/534 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV100115867; called by muse, mutect2
- PEX5L | c.965C>T p.P322L | Missense Mutation (SNP) | VAF 22/416 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.143); catalogued as COSV99828479; called by muse, mutect2
- PHF21B | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 84/375 reads (22%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV100504072; called by muse, mutect2, varscan2
- PLCH1 | c.3020G>A p.R1007K (on ENST00000340059 / NM_001130960.2; = p.R999K on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/220 reads (6%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as rs760913029, COSV58211760; called by muse, mutect2
- PPM1G | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 16/342 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59769259; called by muse, mutect2
- S100A7 | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 88/604 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs143477256; called by muse, mutect2
- SCN1A | c.1703G>A p.R568Q | Missense Mutation (SNP) | VAF 26/476 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs794727025, COSV57668384; ClinVar: uncertain significance; called by muse, mutect2
- SCYL2 | c.2222C>T p.S741F | Missense Mutation (SNP) | VAF 40/499 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.259); catalogued as COSV62568213; called by muse, mutect2
- SEMA3E | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 40/540 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as COSV100317685, COSV57107615; called by muse, mutect2
- SIGLEC8 | c.1384G>A p.G462R | Missense Mutation (SNP) | VAF 54/745 reads (7%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.529); catalogued as COSV58474597; called by muse, mutect2
- SLC39A4 | c.1534G>A p.G512R (on ENST00000301305 / NM_001374839.1; = p.G487R on NM_017767.3) | Missense Mutation (SNP) | VAF 78/920 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM093837, COSV99433813; called by muse, mutect2
- SLFN11 | c.2689C>T p.P897S | Missense Mutation (SNP) | VAF 88/338 reads (26%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.005); catalogued as COSV57701007; called by muse, mutect2, varscan2
- STXBP5L | c.1903G>A p.D635N | Missense Mutation (SNP) | VAF 35/262 reads (13%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.992); catalogued as COSV99876110; called by muse, mutect2, varscan2
- SYNE1 | c.8333C>T p.S2778F (on ENST00000367255 / NM_182961.4; = p.S2785F on NM_033071.3) | Missense Mutation (SNP) | VAF 62/570 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as rs756800860; called by muse, mutect2, varscan2
- TDRD5 | c.2885G>A p.R962Q | Missense Mutation (SNP) | VAF 65/359 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as rs188949880, COSV54249026; called by muse, mutect2, varscan2
- TPSG1 | c.830C>T p.S277F | Missense Mutation (SNP) | VAF 67/672 reads (10%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.885); catalogued as COSV52355296; called by muse, mutect2, varscan2
- TRPV1 | c.2284G>A p.E762K | Missense Mutation (SNP) | VAF 89/417 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51520345; called by muse, mutect2, varscan2
- TXNRD3 | c.1309C>T p.R437C | Missense Mutation (SNP) | VAF 47/276 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1367586511; called by muse, mutect2, varscan2
- UGT2B28 | c.1054C>T p.R352W | Missense Mutation (SNP) | VAF 36/278 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as rs771912824, COSV100158498, COSV59434518; called by muse, mutect2, varscan2
- XPO7 | c.136A>G p.K46E | Missense Mutation (SNP) | VAF 44/312 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.178); catalogued as rs1208720836; called by muse, varscan2
- ZNF142 | c.4592C>T p.S1531F (on ENST00000411696 / NM_001379660.1; = p.S1331F on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 77/696 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as COSV68743018; called by muse, mutect2, varscan2
- ZNF479 | c.1202G>A p.R401K | Missense Mutation (SNP) | VAF 64/772 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV100482551, COSV100482558; called by muse, mutect2
- ZNF675 | c.1483C>T p.L495F | Missense Mutation (SNP) | VAF 41/293 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.961); catalogued as rs978391304; called by muse, mutect2, varscan2
- ABHD17C | c.694C>T p.H232Y | Missense Mutation (SNP) | VAF 62/530 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AC119396.1 | c.831G>A p.G277= | Splice Region (SNP) | VAF 75/417 reads (18%) | called by muse, mutect2, varscan2
- ACOX3 | c.1670C>T p.P557L | Missense Mutation (SNP) | VAF 55/494 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- APC | c.5032G>T p.G1678W | Missense Mutation (SNP) | VAF 18/512 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.554); called by muse, mutect2
- ASTE1 | c.1952C>A p.T651N | Missense Mutation (SNP) | VAF 56/311 reads (18%) | SIFT tolerated (0.64); PolyPhen benign (0); called by mutect2, varscan2
- ATXN7L2 | c.1744A>G p.K582E | Missense Mutation (SNP) | VAF 142/731 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- C1QC | c.316G>A p.G106R | Missense Mutation (SNP) | VAF 154/815 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CALHM4 | c.910G>A p.E304K (on ENST00000368596 / NM_001366078.1; = p.E118K on NM_153036.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/289 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- CAMK1D | c.176T>A p.L59Q | Missense Mutation (SNP) | VAF 39/461 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); called by muse, mutect2
- CGN | c.1655C>T p.A552V | Missense Mutation (SNP) | VAF 76/451 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CLDN4 | c.301G>A p.G101R | Missense Mutation (SNP) | VAF 114/1036 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CSMD1 | c.10471G>A p.A3491T (on ENST00000520002; = p.A3490T on NM_033225.6) | Missense Mutation (SNP) | VAF 56/416 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- CYTIP | c.899G>A p.R300K | Missense Mutation (SNP) | VAF 84/556 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- DNAH8 | c.2104G>A p.D702N | Missense Mutation (SNP) | VAF 27/258 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2
- DPP8 | c.1030A>G p.K344E (on ENST00000341861 / NM_001320875.2; = p.K328E on NM_017743.6) | Missense Mutation (SNP) | VAF 20/325 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); called by muse, mutect2
- DYNC1H1 | c.9521G>A p.R3174H | Missense Mutation (SNP) | VAF 21/542 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ESPNL | c.2864C>T p.A955V | Missense Mutation (SNP) | VAF 79/693 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- EXOC3L2 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 117/593 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- FANCD2 | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 35/313 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- FOXA1 | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 71/611 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FREM1 | c.372G>A p.W124* | Nonsense Mutation (SNP) | VAF 42/411 reads (10%) | called by muse, mutect2
- GSS | c.1214C>T p.P405L | Missense Mutation (SNP) | VAF 86/684 reads (13%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- GSTM3 | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 49/476 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- GTF2IRD2B | c.1543C>T p.P515S | Missense Mutation (SNP) | VAF 41/824 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2
- HNRNPUL1 | c.2110C>T p.P704S | Missense Mutation (SNP) | VAF 91/1010 reads (9%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.045); called by muse, mutect2
- LRP1B | c.13120G>A p.D4374N | Missense Mutation (SNP) | VAF 38/260 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- LRRC42 | c.319C>T p.L107F | Missense Mutation (SNP) | VAF 72/489 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LRRC70 | c.1261C>G p.P421A | Missense Mutation (SNP) | VAF 31/291 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- LTBP2 | c.566C>T p.P189L | Missense Mutation (SNP) | VAF 47/416 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- MAP10 | c.1543C>T p.Q515* | Nonsense Mutation (SNP) | VAF 80/516 reads (16%) | called by muse, mutect2, varscan2
- MAP7D3 | c.883G>A p.V295I | Missense Mutation (SNP) | VAF 66/706 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.027); called by muse, mutect2
- MYT1 | c.1822G>A p.E608K | Missense Mutation (SNP) | VAF 148/701 reads (21%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- NEK11 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 45/242 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- OBSCN | c.152C>T p.A51V | Missense Mutation (SNP) | VAF 130/824 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- PADI2 | c.835G>C p.D279H | Missense Mutation (SNP) | VAF 42/542 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.184); called by muse, mutect2
- PER3 | c.2563C>T p.P855S | Missense Mutation (SNP) | VAF 129/788 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- PGLYRP2 | c.1153C>T p.R385C | Missense Mutation (SNP) | VAF 48/491 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLIN5 | c.1271G>A p.R424K | Missense Mutation (SNP) | VAF 150/703 reads (21%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRKG1 | c.137T>G p.V46G | Missense Mutation (SNP) | VAF 83/556 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- RIOX2 | c.990G>A p.M330I (on ENST00000333396 / NM_001042533.2; = p.M329I on NM_032778.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 85/459 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- RND3 | c.670C>T p.P224S | Missense Mutation (SNP) | VAF 91/679 reads (13%) | SIFT tolerated (0.69); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- RYR2 | c.436G>A p.D146N | Missense Mutation (SNP) | VAF 33/392 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); called by muse, mutect2
- SEPTIN10 | c.1000G>A p.D334N | Missense Mutation (SNP) | VAF 26/596 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2
- SIGLEC9 | c.1213C>T p.H405Y | Missense Mutation (SNP) | VAF 48/276 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- SIM1 | c.1103G>A p.R368K | Missense Mutation (SNP) | VAF 50/642 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.338); called by muse, mutect2
- SLC44A5 | c.2107C>A p.L703M | Missense Mutation (SNP) | VAF 39/344 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SP8 | c.929G>A p.G310E (on ENST00000361443 / NM_198956.4; = p.G328E on NM_182700.6) | Missense Mutation (SNP) | VAF 131/1066 reads (12%) | SIFT tolerated (0.68); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- SPTA1 | c.5490A>T p.E1830D | Missense Mutation (SNP) | VAF 30/504 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2
- SRCIN1 | c.2968C>T p.P990S (on ENST00000621492; = p.P956S on NM_025248.3) | Missense Mutation (SNP) | VAF 40/373 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SRGAP3 | c.2626C>T p.P876S | Missense Mutation (SNP) | VAF 37/620 reads (6%) | SIFT tolerated (0.86); PolyPhen benign (0.068); called by muse, mutect2
- SYBU | c.593C>T p.S198F (on ENST00000276646 / NM_001099754.2; = p.S197F on NM_017786.6) | Missense Mutation (SNP) | VAF 50/546 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2
- SYCP2 | c.1067T>G p.L356R | Missense Mutation (SNP) | VAF 32/264 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SZT2 | c.4093C>T p.P1365S (on ENST00000634258 / NM_001365999.1; = p.P1308S on NM_015284.4) | Missense Mutation (SNP) | VAF 56/659 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0.033); called by muse, mutect2
- TMEM128 | c.275G>A p.S92N (on ENST00000382753 / NM_001297552.2; = p.S68N on NM_032927.3) | Missense Mutation (SNP) | VAF 47/305 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- TNXB | c.7118C>T p.T2373I (on ENST00000647633; = p.T2126I on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 76/933 reads (8%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.755); called by muse, mutect2
- TRIM52 | c.230G>C p.G77A | Missense Mutation (SNP) | VAF 117/565 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- TRO | c.871T>G p.S291A | Missense Mutation (SNP) | VAF 60/578 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- TSPOAP1 | c.444G>A p.R148= | Splice Region (SNP) | VAF 35/277 reads (13%) | called by muse, mutect2, varscan2
- USP20 | c.1910G>A p.G637D | Missense Mutation (SNP) | VAF 40/388 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- VWA5B2 | c.2609C>T p.S870L | Missense Mutation (SNP) | VAF 48/630 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.115); called by muse, mutect2
- WDR88 | c.914G>A p.G305E | Missense Mutation (SNP) | VAF 43/580 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2
- XAB2 | c.241_246del p.Q81_V82del | In Frame Del (DEL) | VAF 74/478 reads (15%) | called by mutect2, pindel, varscan2
- YBX2 | c.1022C>T p.P341L | Missense Mutation (SNP) | VAF 69/603 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ZFHX2 | c.3859G>A p.G1287R | Missense Mutation (SNP) | VAF 117/558 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- ZNF676 | c.1730C>T p.S577F (on ENST00000650058; = p.S545F on NM_001001411.3) | Missense Mutation (SNP) | VAF 70/368 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- ZNF843 | c.700C>T p.P234S | Missense Mutation (SNP) | VAF 159/711 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- ZYX | c.667C>T p.H223Y | Missense Mutation (SNP) | VAF 84/1188 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.024); called by muse, mutect2
- ADAM21 | c.1371C>T p.F457= | Silent (SNP) | VAF 45/420 reads (11%) | catalogued as COSV50814786; called by muse, mutect2, varscan2
- ADAMTSL2 | c.1593C>T p.F531= | Silent (SNP) | VAF 60/571 reads (11%) | called by muse, mutect2, varscan2
- ADCK1 | c.1425A>C p.S475= | Silent (SNP) | VAF 32/356 reads (9%) | catalogued as rs752781136; called by muse, mutect2
- ADGRB3 | c.4131C>T p.P1377= | Silent (SNP) | VAF 57/382 reads (15%) | called by muse, mutect2, varscan2
- ALLC | c.1062C>T p.P354= | Silent (SNP) | VAF 35/618 reads (6%) | called by muse, mutect2
- ATP13A5 | c.1857C>T p.F619= | Silent (SNP) | VAF 26/474 reads (5%) | catalogued as COSV60873626; called by muse, mutect2
- BGN | c.513C>T p.I171= | Silent (SNP) | VAF 122/621 reads (20%) | called by muse, mutect2, varscan2
- C18orf63 | c.168A>T p.T56= | Silent (SNP) | VAF 34/291 reads (12%) | called by muse, mutect2, varscan2
- C2CD2 | c.927C>T p.D309= | Silent (SNP) | VAF 26/509 reads (5%) | called by muse, mutect2
- CABS1 | c.315C>T p.S105= | Silent (SNP) | VAF 87/376 reads (23%) | called by muse, mutect2, varscan2
- CAPN13 | c.918G>A p.K306= | Silent (SNP) | VAF 110/455 reads (24%) | catalogued as COSV99700746; called by muse, mutect2, varscan2
- CLDN4 | c.300G>A p.V100= | Silent (SNP) | VAF 111/1036 reads (11%) | called by muse, mutect2, varscan2
- CROCC | c.1557C>T p.S519= | Silent (SNP) | VAF 151/1222 reads (12%) | called by muse, mutect2
- CYSLTR1 | c.537C>T p.D179= | Silent (SNP) | VAF 44/424 reads (10%) | catalogued as COSV64820140; called by muse, mutect2, varscan2
- DLEU7 | c.231G>A p.R77= | Silent (SNP) | VAF 40/748 reads (5%) | called by muse, mutect2
- DYRK4 | c.106C>T p.L36= | Silent (SNP) | VAF 84/330 reads (25%) | called by muse, mutect2, varscan2
- EFHD1 | c.159G>A p.A53= | Silent (SNP) | VAF 70/898 reads (8%) | catalogued as rs1051883408; called by muse, mutect2
- EIF2AK3 | c.1030T>C p.L344= | Silent (SNP) | VAF 43/245 reads (18%) | called by muse, mutect2, varscan2
- FAM135B | c.3936T>G p.A1312= | Silent (SNP) | VAF 27/538 reads (5%) | called by muse, mutect2
- FAM83H | c.1755C>T p.S585= | Silent (SNP) | VAF 97/822 reads (12%) | called by muse, mutect2, varscan2
- FLNC | c.864G>A p.Q288= | Silent (SNP) | VAF 95/946 reads (10%) | catalogued as rs201906839; called by muse, mutect2, varscan2
- GSS | c.1215T>A p.P405= | Silent (SNP) | VAF 84/684 reads (12%) | called by muse, mutect2, varscan2
- KALRN | c.8361C>T p.I2787= (on ENST00000360013 / NM_001024660.4; = p.I1090= on NM_007064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 48/374 reads (13%) | catalogued as COSV99361312; called by muse, mutect2, varscan2
- KEL | c.1815G>A p.Q605= | Silent (SNP) | VAF 82/1044 reads (8%) | called by muse, mutect2
- KIRREL2 | c.483C>T p.F161= | Silent (SNP) | VAF 60/563 reads (11%) | called by muse, mutect2, varscan2
- KRT18 | c.609C>T p.I203= | Silent (SNP) | VAF 55/440 reads (13%) | catalogued as rs752822458, COSV66315854, COSV66316767; called by muse, mutect2, varscan2
- LRP1 | c.2703G>A p.K901= | Silent (SNP) | VAF 108/461 reads (23%) | catalogued as COSV99675005; called by muse, mutect2, varscan2
- MIDEAS | c.15C>T p.A5= | Silent (SNP) | VAF 53/422 reads (13%) | called by muse, mutect2, varscan2
- MUC16 | c.25953G>A p.G8651= | Silent (SNP) | VAF 74/597 reads (12%) | catalogued as COSV67489141, COSV67490200; called by muse, mutect2, varscan2
- MYRF | c.1110G>A p.K370= (on ENST00000278836 / NM_001127392.3; = p.K361= on NM_013279.4) | Silent (SNP) | VAF 61/391 reads (16%) | called by muse, mutect2, varscan2
- NEFM | c.2391G>A p.K797= | Silent (SNP) | VAF 57/460 reads (12%) | catalogued as rs1257300887; called by muse, mutect2, varscan2
- NRXN1 | c.3684G>A p.V1228= | Silent (SNP) | VAF 52/662 reads (8%) | called by muse, mutect2
- PCDHA7 | c.954C>T p.I318= | Silent (SNP) | VAF 106/755 reads (14%) | catalogued as rs782311371; called by muse, mutect2, varscan2
- PNCK | c.594G>A p.L198= (on ENST00000340888 / NM_001366975.1; = p.L281= on NM_001039582.3) | Silent (SNP) | VAF 120/609 reads (20%) | catalogued as COSV61742838; called by muse, mutect2, varscan2
- PRR16 | c.795G>A p.G265= (on ENST00000407149 / NM_001300783.2; = p.G242= on NM_016644.2) | Silent (SNP) | VAF 44/582 reads (8%) | called by muse, mutect2
- RGL4 | c.537G>A p.G179= | Silent (SNP) | VAF 120/672 reads (18%) | catalogued as rs1261272975; called by muse, mutect2, varscan2
- RPS5 | c.486C>T p.A162= | Silent (SNP) | VAF 41/427 reads (10%) | catalogued as rs775094026; called by muse, mutect2
- SALL1 | c.2541C>T p.S847= | Silent (SNP) | VAF 121/556 reads (22%) | catalogued as COSV51763222; called by muse, mutect2, varscan2
- SCN10A | c.210C>T p.L70= | Silent (SNP) | VAF 39/498 reads (8%) | called by muse, mutect2
- SEC31B | c.2712C>T p.F904= | Silent (SNP) | VAF 68/464 reads (15%) | catalogued as COSV64845030; called by muse, mutect2, varscan2
- SERTAD4 | c.450C>T p.C150= | Silent (SNP) | VAF 54/475 reads (11%) | catalogued as COSV100882676; called by muse, mutect2, varscan2
- SF3B2 | c.1791C>T p.F597= | Silent (SNP) | VAF 42/524 reads (8%) | catalogued as rs778816554, COSV59427013; called by muse, mutect2
- SH2D4B | c.654C>T p.S218= | Silent (SNP) | VAF 39/295 reads (13%) | called by muse, mutect2, varscan2
- SIGLEC8 | c.1383G>A p.Q461= | Silent (SNP) | VAF 54/751 reads (7%) | called by muse, mutect2
- SLC38A3 | c.582C>T p.I194= | Silent (SNP) | VAF 33/347 reads (10%) | called by muse, mutect2, varscan2
- SLC9A2 | c.705C>T p.L235= | Silent (SNP) | VAF 81/454 reads (18%) | called by muse, mutect2, varscan2
- SPTBN5 | c.9921C>T p.G3307= | Silent (SNP) | VAF 139/718 reads (19%) | catalogued as rs778632826, COSV58024997; called by muse, mutect2, varscan2
- SSTR5 | c.963C>T p.L321= | Silent (SNP) | VAF 70/613 reads (11%) | called by muse, mutect2, varscan2
- TIPARP | c.657C>A p.S219= | Silent (SNP) | VAF 24/457 reads (5%) | called by muse, mutect2
- TTN | c.24768C>T p.I8256= (on ENST00000591111; = p.I7329= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 78/356 reads (22%) | catalogued as rs878991106, COSV59945668; called by muse, mutect2, varscan2
- TXK | c.1167G>A p.R389= | Silent (SNP) | VAF 18/217 reads (8%) | called by muse, mutect2
- ZBTB7B | c.1542C>T p.T514= (on ENST00000292176; = p.T548= on NM_001252406.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 82/752 reads (11%) | called by muse, mutect2, varscan2
- ZSCAN20 | c.1029C>T p.F343= | Silent (SNP) | VAF 37/564 reads (7%) | catalogued as rs765146766, COSV63683840; called by muse, mutect2
- ZSWIM2 | c.534G>A p.K178= | Silent (SNP) | VAF 25/167 reads (15%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73822152 G>A | 5'Flank (SNP) | VAF 37/429 reads (9%) | called by muse, mutect2
- ANKRD24 | c.37-1425C>T | Intron (SNP) | VAF 77/728 reads (11%) | called by muse, mutect2
- DOK3 | chr5:177503228 C>T | 3'Flank (SNP) | VAF 124/509 reads (24%) | called by muse, mutect2, varscan2
- OBSCN | c.11660-1167C>T | Intron (SNP) | VAF 72/558 reads (13%) | called by muse, mutect2, varscan2
- SLC39A1 | c.*834A>G | 3'UTR (SNP) | VAF 108/599 reads (18%) | called by muse, mutect2, varscan2
- Y_RNA | chr16:11316862 C>A | 3'Flank (SNP) | VAF 51/407 reads (13%) | called by muse, mutect2, varscan2
